Gene-level copy-number profile of specimen HCM-BROD-0481-C43-85M from HCMI case HCM-BROD-0481-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.5 years (23,182 days).
Specimen HCM-BROD-0481-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b9963b9b-f3ea-484d-b510-ea922790e5a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0481-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/3ad9b350-6da5-445a-bf4b-de7c122c83e8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 204; copy number 2: 19,383; copy number 3: 32,961; copy number 4: 1,529; copy number 5: 1,269; copy number 6: 2,659; copy number 7: 6; copy number 8: 8; copy number 9: 221; copy number 10: 103; copy number 11: 2; copy number 12: 23; copy number 13: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 374 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:58,237,532–90,261,708, 294 genes, copy number 9–10 (broad region; genes not listed).
- chr5:34,838,833–34,899,456, 3 genes, copy number 7 (within-gene range 2–7): TTC23L, AC026801.1, RPL21P54.
- chr9:11,618,496–12,058,227, 2 genes, copy number 7: AL592227.1, AL353595.1.
- chr9:13,386,130–19,464,524, 75 genes, copy number 7–13 (within-gene range 6–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
